Gene-level copy-number profile of tumor specimen ALCH-B2XX-TTP1-A from ALCHEMIST case ALCH-B2XX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 69.7 years (25,458 days).
Specimen ALCH-B2XX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 180a0627-74de-4790-87b6-328e663146c4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2XX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/6264b002-ce94-48e4-84fb-5bf712995a28

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 1,080; copy number 2: 56,308; copy number 3: 968; copy number 4: 17; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:95,274,449–95,291,308, 1 gene: PROM2.
- chr2:131,527,675–131,536,988, 2 genes: CCDC74A, MED15P4.
- chr6:166,383,189–166,389,920, 2 genes: AL022069.1, AL022069.2.
- chr7:62,275,361–63,060,084, 4 genes: AC128676.1, RNU6-417P, AC069285.2, AC069285.3.
- chr8:43,672,823–46,028,892, 3 genes: AC139365.2, AC139365.1, AC118650.1.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr15:63,928,274–63,935,953, 1 gene (within-gene range 0–2): AC015914.1.
- chr16:69,299,682–69,339,583, 5 genes (within-gene range 0–2): AC026464.4, VPS4A, COG8, PDF, AC026464.6.
- chr19:19,515,736–19,537,581, 3 genes: NDUFA13, AC011448.1, YJEFN3.
- chr19:27,638,483–27,646,483, 2 genes: ERVK-28, AC112702.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:130,044,713–130,045,081, 1 gene, copy number 5: AL136141.1.
- chr21:12,999,676–13,016,692, 1 gene, copy number 5: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 759. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
